Somatic mutation profile of tumor specimen MP2PRT-PASLLA-TMP1-A (aliquot MP2PRT-PASLLA-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASLLA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,129 days).
Specimen MP2PRT-PASLLA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a880db5c-29b6-41c5-8add-7739090b042a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLLA-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLLA-NB1-B-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cd4f4d-4c5b-4ca1-98e9-38b05b4e79ac

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67098419; called by muse, mutect2
- APBA3 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 39/497 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1472123862, COSV100349772; called by muse, mutect2
- FAT4 | c.11819C>T p.S3940L | Missense Mutation (SNP) | VAF 19/383 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1342514440; called by muse, mutect2
- FKRP | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 254/556 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1252655162, COSV59358714; called by muse, varscan2
- GAD2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 109/353 reads (31%) | catalogued as rs897876627, COSV52150849; called by muse, mutect2, varscan2
- HDAC2 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 99/358 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64038562; called by muse, mutect2, varscan2
- PDE3A | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100762644; called by muse, mutect2
- RTN2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 35/509 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs570062973, COSV55593784; called by muse, mutect2
- SPHKAP | c.4582G>A p.D1528N | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs767681152; called by muse, mutect2, varscan2
- UBE2D2 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV99551400; called by muse, mutect2
- ABCC3 | c.3571T>C p.S1191P | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ADO | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 37/693 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2
- ATP13A5 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND6A | c.1268_1269insCCTCGT p.V423_Q424insLV | In Frame Ins (INS) | VAF 58/158 reads (37%) | called by mutect2, pindel, varscan2
- DHX30 | c.1969G>A p.D657N (on ENST00000445061 / NM_138615.3; = p.D618N on NM_014966.3) | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2
- DHX30 | c.2318G>C p.R773T (on ENST00000445061 / NM_138615.3; = p.R734T on NM_014966.3) | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by mutect2, varscan2
- FAT3 | c.7747T>A p.F2583I | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- FUBP3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IRAK3 | c.10A>C p.N4H | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KIAA1671 | c.1569A>C p.E523D | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.136); called by muse, varscan2
- MYO5B | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2
- TFAP2A | c.788G>C p.G263A (on ENST00000482890; = p.G255A on NM_001032280.3) | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM121B | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 32/449 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- TRBJ2-5 | c.3del p.Q2Kfs*? | Frame Shift Del (DEL) | VAF 125/157 reads (80%) | called by pindel*, varscan2
- VWDE | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2
- ACAN | c.1908C>A p.I636= | Silent (SNP) | VAF 216/473 reads (46%) | catalogued as COSV100719207, COSV61371563; called by muse, mutect2, varscan2
- NUDT8 | c.339C>G p.T113= | Silent (SNP) | VAF 85/206 reads (41%) | called by muse, mutect2, varscan2
- SP5 | c.864G>A p.A288= | Silent (SNP) | VAF 42/488 reads (9%) | catalogued as COSV64623616; called by muse, mutect2
- UNC80 | c.1605G>C p.L535= | Silent (SNP) | VAF 40/343 reads (12%) | called by muse, mutect2, varscan2
- COL6A5 | c.*42G>A | 3'UTR (SNP) | VAF 15/70 reads (21%) | catalogued as rs969648462; called by muse, mutect2, varscan2
